Somatic mutation profile of tumor specimen TCGA-B0-5097-01A (aliquot TCGA-B0-5097-01A-01D-1421-08) from TCGA case TCGA-B0-5097, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.8 years (21,852 days).
Specimen TCGA-B0-5097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c4c79e9-2a60-4d9f-964a-72e227bade01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5097-11A (Solid Tissue Normal), aliquot TCGA-B0-5097-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8784f2-733f-488d-b0ca-7da1d5b67a8c

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 25/135 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- VHL | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs5030803, CM961417, COSV56542909, COSV56544662, COSV56545202, COSV56545701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF2 | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54000089; called by muse, mutect2, varscan2
- ALAS2 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV58192405; called by muse, mutect2, varscan2
- ASTL | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV60904921, COSV60905600; called by muse, mutect2, varscan2
- ATM | c.7738A>T p.R2580* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as COSV53761993; called by muse, mutect2, varscan2
- BAP1 | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56230932, COSV56232984; called by muse, mutect2, varscan2
- CD180 | c.731A>C p.N244T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV56519202; called by muse, mutect2, varscan2
- CHERP | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52226644; called by muse, mutect2, varscan2
- CLOCK | c.1539+2T>C p.X513_splice | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as COSV59403978; called by muse, mutect2, varscan2
- CLOCK | c.1539+1G>T p.X513_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | catalogued as COSV59403995; called by muse, mutect2, varscan2
- CSPP1 | c.3017A>T p.K1006M (on ENST00000676605; = p.K965M on NM_024790.6) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51589395; called by muse, mutect2, varscan2
- CYP11B2 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59997167; called by muse, mutect2, varscan2
- DCAF4L1 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV60788100; called by muse, mutect2, varscan2
- DNAH11 | c.12143C>A p.P4048H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754738080, COSV60969984; called by muse, mutect2, varscan2
- DNAH7 | c.10936G>A p.V3646M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56776672; called by muse, mutect2, varscan2
- DOCK10 | c.1488T>G p.F496L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV51422500; called by muse, mutect2, varscan2
- EPS15L1 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs974185123, COSV50172314; called by muse, mutect2, varscan2
- EYS | c.44A>T p.H15L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV60994785; called by muse, mutect2, varscan2
- FBLN2 | c.2606G>T p.C869F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55488616; called by muse, mutect2, varscan2
- GK | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV66734636; called by muse, mutect2
- GNA14 | c.623A>C p.E208A | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59027066; called by muse, mutect2
- LTN1 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63734706; called by muse, mutect2
- MTUS2 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV70919019; called by muse, mutect2, varscan2
- MYOT | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs756669574, COSV53515714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAB1 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV61609168; called by muse, mutect2, varscan2
- NR1H4 | c.770C>G p.T257S (on ENST00000551379 / NM_001206993.2; = p.T243S on NM_005123.4) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV51855004; called by muse, mutect2, varscan2
- PDE4DIP | c.5693C>G p.P1898R | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV100519564, COSV57717090; called by muse, mutect2, varscan2
- PHF23 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV50038113; called by muse, mutect2
- PIGG | c.1488T>A p.S496R (on ENST00000453061 / NM_001127178.3; = p.S488R on NM_017733.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV56320170; called by muse, mutect2, varscan2
- PSG3 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59505915; called by muse, mutect2, varscan2
- RABEP2 | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV62870376; called by muse, varscan2
- SALL1 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs748725958, COSV51756537, COSV51761688; called by muse, mutect2, varscan2
- SDK2 | c.5458C>A p.P1820T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66192361; called by muse, mutect2, varscan2
- SLC27A1 | c.1476C>G p.D492E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099375, COSV53101346; called by muse, mutect2, varscan2
- SMARCE1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62177350; called by muse, varscan2
- SPRY2 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65701649; called by muse, mutect2, varscan2
- SPSB1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV60164140; called by muse, mutect2, varscan2
- SRSF4 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs111495066, COSV65695400; called by muse, mutect2, varscan2
- TBC1D25 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65124222; called by muse, mutect2
- TCF21 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1355399056, COSV52818980; called by muse, mutect2, varscan2
- TEX13A | c.1179G>T p.R393S | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61170872; called by muse, mutect2, varscan2
- TMPRSS11D | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as COSV52224985; called by muse, mutect2, varscan2
- TNPO1 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs771796017, COSV61523139; called by muse, mutect2
- TOR3A | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61680567; called by muse, mutect2, varscan2
- TYK2 | c.3122A>C p.D1041A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53389848; called by mutect2, varscan2
- UIMC1 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 33/182 reads (18%) | catalogued as rs755699734, COSV65894487; called by muse, mutect2
- ATM | c.1487del p.S496Ifs*16 | Frame Shift Del (DEL) | VAF 33/211 reads (16%) | called by mutect2, pindel, varscan2
- DNA2 | c.1874-28_1888del p.X625_splice | Splice Site (DEL) | VAF 50/291 reads (17%) | called by mutect2, pindel
- EPHA3 | c.1985del p.K662Sfs*35 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | called by mutect2, pindel, varscan2
- KMT2C | c.538del p.T180Pfs*26 | Frame Shift Del (DEL) | VAF 55/350 reads (16%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4016del p.P1339Lfs*45 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- SNAP91 | c.2024del p.G675Vfs*11 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- ALMS1 | c.4071T>A p.A1357= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as COSV52516978; called by muse, mutect2, varscan2
- COG6 | c.1146A>G p.K382= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV62997359; called by muse, mutect2, varscan2
- FLVCR2 | c.93C>A p.P31= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV53163737; called by muse, mutect2, varscan2
- GCLM | c.171A>G p.Q57= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV64687348; called by muse, mutect2, varscan2
- GZF1 | c.1428C>T p.H476= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs1487546611, COSV57637285; called by muse, mutect2, varscan2
- MAEL | c.405C>T p.L135= | Silent (SNP) | VAF 49/230 reads (21%) | catalogued as rs1379914991, COSV63305810; called by muse, mutect2, varscan2
- POLR2H | c.228C>T p.N76= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV55603142; called by muse, mutect2, varscan2
- SVEP1 | c.2469G>A p.E823= | Silent (SNP) | VAF 47/401 reads (12%) | catalogued as rs1372501017, COSV57043064; called by muse, mutect2, varscan2
- VHL | c.222C>T p.V74= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs759737367, COSV56557484; called by muse, mutect2, varscan2
- WDR64 | c.1002G>A p.K334= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs768150650, COSV63798493; called by muse, mutect2, varscan2
- ZNF655 | c.555G>A p.Q185= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV53159508; called by muse, mutect2, varscan2
- ATP6AP1L | n.1928G>T | RNA (SNP) | VAF 9/65 reads (14%) | catalogued as COSV66475345; called by muse, mutect2, varscan2
- MIR450A1 | n.4C>T | RNA (SNP) | VAF 21/96 reads (22%) | catalogued as rs941721630; called by muse, mutect2, varscan2
